MMRF case MMRF_1543 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/44ba04d6-7a2b-4d8f-8d52-6975e141c2ab

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 63 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 63.1 years (23,046 days); ISS stage: I; Days to last known disease status: 1,265 days (3.5 years); Days to last follow up: 1,265 days (3.5 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 109 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 143 days; Days to treatment end: 143 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 144 days; Days to treatment end: 144 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -23: M Protein 2.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.71 mg/dL; Immunoglobulin G 29.4 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.36 g/L; Beta 2 Microglobulin 1.6 µg/mL; Lactate Dehydrogenase 2.55 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.44 ×10⁹/L; Platelets 220 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 9 g/dL; Glucose 5.28 mmol/L; C-Reactive Protein 0.139 mg/dL.
- Day 78: Hemoglobin 7.5 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 3.78 ×10⁹/L; Platelets 262 ×10⁹/L.
- Day 170 (ECOG 1): M Protein 0.26 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.83 mg/dL; Immunoglobulin G 7.76 g/L; Immunoglobulin A 0.71 g/L; Immunoglobulin M 0.65 g/L; Beta 2 Microglobulin 0.89 µg/mL; Lactate Dehydrogenase 4.75 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 46 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.35 mmol/L; Albumin 35 g/L; Total Protein 6.6 g/dL; Glucose 6 mmol/L.
- Day 257 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.44 mg/dL; Immunoglobulin G 5.94 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 2.62 µg/mL; Lactate Dehydrogenase 2.55 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.14 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 49.5 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.45 mmol/L; Albumin 41 g/L; Total Protein 7.3 g/dL; Glucose 5.01 mmol/L.
- Day 348 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.85 mg/dL; Immunoglobulin G 9.9 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.51 g/L; Beta 2 Microglobulin 1.54 µg/mL; Lactate Dehydrogenase 2.25 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.56 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 7.1 g/dL; Glucose 4.62 mmol/L.
- Day 502 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.319 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.06 mg/dL; Immunoglobulin G 11.6 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.71 g/L; Beta 2 Microglobulin 2.1 µg/mL; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.22 ×10⁹/L; Platelets 229 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.35 mmol/L; Albumin 45 g/L; Total Protein 8 g/dL; Glucose 4.84 mmol/L.
- Day 611: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.58 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.3 mg/dL; Immunoglobulin G 12.1 g/L; Immunoglobulin A 0.39 g/L; Immunoglobulin M 0.89 g/L; Beta 2 Microglobulin 2.26 µg/mL; Lactate Dehydrogenase 7.87 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 3.2 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 7.6 g/dL; Glucose 4.4 mmol/L.
- Day 745: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.97 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.11 mg/dL; Immunoglobulin G 9.47 g/L; Immunoglobulin A 0.42 g/L; Immunoglobulin M 0.95 g/L; Beta 2 Microglobulin 1.71 µg/mL; Lactate Dehydrogenase 7.33 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 3.9 ×10⁹/L; Platelets 239 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 7.4 g/dL; Glucose 4.18 mmol/L.
- Day 880 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.57 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.38 mg/dL; Immunoglobulin G 10.9 g/L; Immunoglobulin A 0.99 g/L; Immunoglobulin M 0.93 g/L; Beta 2 Microglobulin 1.91 µg/mL; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.5 mmol/L; Albumin 41 g/L; Total Protein 7.6 g/dL; Glucose 5.01 mmol/L.
- Day 1,045: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.5 mg/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 0.68 g/L; Immunoglobulin M 1 g/L; Beta 2 Microglobulin 1.56 µg/mL; Lactate Dehydrogenase 8.1 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 3.1 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 62.8 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.45 mmol/L; Albumin 46 g/L; Total Protein 7.3 g/dL; Glucose 4.24 mmol/L.
- Day 1,136: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.75 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.56 mg/dL; Immunoglobulin G 11.7 g/L; Immunoglobulin A 0.81 g/L; Immunoglobulin M 1.11 g/L; Beta 2 Microglobulin 1.12 µg/mL; Lactate Dehydrogenase 7.9 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 2.9 ×10⁹/L; Platelets 231 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.5 mmol/L; Albumin 44 g/L; Total Protein 7.9 g/dL; Glucose 4.73 mmol/L.
- Day 1,265 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.86 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.42 mg/dL; Immunoglobulin G 11.9 g/L; Immunoglobulin A 0.79 g/L; Immunoglobulin M 0.96 g/L; Beta 2 Microglobulin 1.56 µg/mL; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.48 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.43 mmol/L; Albumin 43 g/L; Total Protein 7.4 g/dL; Glucose 5.12 mmol/L.

Other clinical attributes
- Day -23: Weight: 68 kg; Height: 160 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Breast Cancer.

Biospecimens (2 samples)
- Sample MMRF_1543_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -23 days.
- Sample MMRF_1543_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -23 days.
